Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3458, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3458-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Copy To:

Clinical History/Diagnosis: Right Renal Mass

Source of Specimen(s):

Right kidney, perirenal fat and adrenal gland

Gross Description:

Received in one part.

Source of Tissue: 1. Labeled #1, "right kidney, perirenal fat and adrenal"

Gross Description: Received fresh labeled, right kidney, perirenal fat and adrenal". It consists of a kidney with surrounding perinephric fat weighing a total of 1109 grams. The attached ureter measures 13 cm in length and 0.5 cm in diameter. The ureter is opened to reveal a smooth tan-pink mucosa with no papillary structures noted. The specimen is bisected revealing a 13.5 x 8 x 6 cm kidney that weighs 370 grams. A firm well-demarcated, variegated mid pole mass is identified measuring 6.5 x 6.5 x 4 cm and comes within less than 0.1 cm of the capsule. Grossly the mass does not appear to infiltrate the surrounding perinephric fat. The remaining parenchyma is light-brown, soft with no other discrete lesions present. The adrenal gland cannot be identified grossly. Representative sections are submitted in 1A-1L. Tissue sent for Cytogenetics.

Designation of Sections: 1A- ureteral and vascular margins, 1B- additional sections of ureter, 1C-1D- tumor with closest capsule, 1E-1F- sections of perinephric fat closest to tumor, 1G-1H- tumor with adjacent normal kidney, 1I-1L- perinephric fat to look for adrenal gland

Final Diagnosis:

1. Right kidney, perineural fat and adrenal gland, radical nephrectomy:
- Renal cell carcinoma, clear cell type, 6.5 cm in greatest dimension grossly, Fuhrman nuclear grade III of IV.
- Carcinoma is confined to the kidney.
- Lymphovascular invasion is not identified.
- Vascular and ureteral resection margins are free of tumor.
- No adrenal gland is identified.

pTNM: T1b Nx Mx

Source: NCI Genomic Data Commons file 983df58e-9882-46e9-9327-2bd5dde2378e (TCGA-AK-3458.F60E8526-3D2E-4526-A393-431291059BD3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).